Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAVW, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAVW-01A (Primary Tumor).

DIAGNOSIS:

Liver, left, hemihepatectomy:

Hepatocellular carcinoma, S2

- 1) Post-chemoembolization status: absent
- 2) Size of tumor: 2.2x2x1.5cm
- 3) Gross type: infiltrative
- 4) Satellite nodule: absent
- 5) Histologic type: trabecular
- 6) Cell type: classic and clear cell group
- 7) Edmondson and Steiner's histologic grade:
The worst differentiation: 3
The major differentiation: 2
- 8) Fatty change: present (5%)
- 9) Hemorrhage/peliosis: absent
- 10) Tumor necrosis: absent
- 11) Vascular invasion(microscopic): absent
- 12) Capsule formation: partial
- 13) Infiltration of capsule: absent
- 14) Septal formation: present
- 15) Involvement of a major branch of the portal vein: absent
- 16) Involvement of a major branch of the hepatic vein: absent
- 17) Bile duct invasion: present, extensive
- 18) Serosal invasion: present (Glisson's capsule)
- 19) Surgical margin: clear (safety margin: 1.2cm)
- 20) Intrahepatic metastasis: absent
- 21) Multicentric occurrence: absent
- 22) Pathologic stage: AJCC (pT1), (pT2)
- 23) Related biopsy: none
- 24) Additional pathologic findings
- a) Cirrhosis: present, inactive, HBV-associated
- b) Dysplasia: absent

ICD O-3

Carcinoma, hepatocellular NOS
8170/3

Site Liver C22.0

4/22/14

Gallbladder, cholecystectomy:

Cholesterosis

Source: NCI Genomic Data Commons file 61173cce-79ed-4b03-be23-94af5953bd8c (TCGA-DD-AAVW.922707E9-9F68-458F-B1FC-E95CA2876420.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).